Gene-level copy-number profile of tumor specimen TCGA-AA-A00U-01A from TCGA case TCGA-AA-A00U, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 50.0 years (18,263 days).
Specimen TCGA-AA-A00U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fa6eb6bd-0761-458c-b19c-e9166eccbad0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98688e54-f76c-472c-8f92-4e8300665121

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 8,381; copy number 2: 48,618; copy number 3: 2,756; copy number 4: 509.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A00U-01): tumor purity 0.76, ploidy 1.98, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:59,049,399–59,133,250, 4 genes: AC092757.1, CCNB2, AC092757.3, AC092757.2.
- chr15:59,171,183–59,171,262, 1 gene: MIR2116.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–1): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
